MMRF case MMRF_2584 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bba731c5-eaf8-4693-bf18-f233f05a3279

Demographics
Sex at birth: female; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.1 years (20,839 days); ISS stage: II; Days to last known disease status: 505 days (1.4 years); Days to last follow up: 505 days (1.4 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 159 days; Days to treatment end: 159 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -4, day 505.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Serum Free Immunoglobulin Light Chain, Kappa 17.1 mg/dL.
- Absolute Neutrophil 6.24 ×10⁹/L.
- Hemoglobin 5.7 mmol/L.
- Creatinine 52.2 µmol/L.
- Calcium 2.01 mmol/L.
- Serum Free Immunoglobulin Light Chain, Lambda 172 mg/dL.
- Albumin 43.7 g/L.
- Lactate Dehydrogenase 2.67 µkat/L.
- Platelets 245 ×10⁹/L.
- M Protein 5.27 g/dL.
- Beta 2 Microglobulin 4.5 µg/mL.

Other clinical attributes
- Day -4: Weight: 48 kg; Height: 155 cm.

Biospecimens (2 samples)
- Sample MMRF_2584_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2584_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
